CGCI case BLGSP-71-23-00440 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de25e05f-3db7-4754-8f5b-dd8b95a7942e

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 22 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 22.3 years (8,143 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,863 days (5.1 years); Ann Arbor extranodal involvement: Yes; Sites of involvement: Colon, NOS / Ovary, NOS.
   Pathology details: Bone marrow malignant cells: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 1,863 days (5.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Negative.
- Lactate Dehydrogenase 238 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 48 kg; Height: 162 cm; BMI: 18.3.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00440-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00440-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00440-01-Ki67: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-CD10: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-BCL2: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-CD20: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-BCL6: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-HE-1: Tissue microarray coordinates: A1,E3,B4.
  Slide BLGSP-71-23-00440-01-CD3: Tissue microarray coordinates: A1,E3,B4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Surgical; Days from index date to tumor sample procurement: -26; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Colon; Extranodal involvement site: Ovary.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 238; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
